Gene-level copy-number profile of tumor specimen TARGET-10-PATBRV-09A from TARGET case TARGET-10-PATBRV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,054 days).
Specimen TARGET-10-PATBRV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.35ebc00e-8045-51eb-bb22-eea5cfc2bd53.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATBRV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate.
https://portal.gdc.cancer.gov/files/e9b97660-bbaf-4a6c-865b-abbf5a3abaec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 586; copy number 1: 57; copy number 2: 59,074; copy number 3: 248; copy number 4: 185; copy number 5: 1; copy number 6: 4; copy number 7: 107; copy number 8: 7.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:26,015,669–26,016,369, 1 gene: RPEP2.
- chr4:1,100,016–1,132,977, 2 genes (within-gene range 0–2): AC092535.3, AC092535.4.
- chr4:1,118,884–1,119,013, 1 gene: AC092535.1.
- chr5:403,731–404,546, 1 gene: AC010442.1.
- chr7:38,256,337–38,378,804, 21 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr14:22,105,343–22,482,959, 29 genes (within-gene range 0–2): TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:100,333,790–100,376,805, 1 gene (within-gene range 0–2): WARS1.
- chr14:100,366,628–100,366,920, 1 gene: AL157871.3.
- chr17:36,012,504–36,017,972, 2 genes: AC244100.4, CCL23.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 119 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,181,308–135,497,765, 7 genes, copy number 8 (within-gene range 2–8): MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2.
- chr13:19,026,001–19,032,626, 2 genes, copy number 6: GTF2IP3, AL137001.1.
- chr14:105,836,765–106,397,114, 107 genes, copy number 7 (broad region; genes not listed).
- chr15:23,430,839–23,447,243, 2 genes, copy number 6: HERC2P6, GOLGA6L2.
- chr19:19,176,903–19,192,591, 1 gene, copy number 5 (within-gene range 2–5): BORCS8.

Autosomal genes at a single copy (total copy number 1): 57. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
